Somatic mutation profile of tumor specimen TCGA-ZS-A9CE-01A (aliquot TCGA-ZS-A9CE-01A-11D-A36X-10) from TCGA case TCGA-ZS-A9CE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 79.5 years (29,051 days).
Specimen TCGA-ZS-A9CE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cd2bdd2-7e34-419a-9617-e07e977f5bde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZS-A9CE-10A (Blood Derived Normal), aliquot TCGA-ZS-A9CE-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bdff2c12-7031-403b-b7f6-fc5772596b23

The open-access MAF lists 133 somatic variants for this specimen: 103 protein-altering or splice-affecting, 26 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 26, Nonsense Mutation 9, Frame Shift Del 5, Intron 3, Frame Shift Ins 3, In Frame Del 2, Splice Region 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1634A>C p.E545A | Missense Mutation (SNP) | VAF 183/382 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs121913274, CM130273, COSV55873209, COSV55873220, COSV55892885; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.82701C>A p.Y27567* (on ENST00000591111; = p.Y20143* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 47/65 reads (72%) | catalogued as rs772121356, CM121833, COSV100634799; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.4226G>A p.R1409H | Missense Mutation (SNP) | VAF 57/104 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs142258568, COSV99288928; called by muse, mutect2, varscan2
- AGO4 | c.1880G>T p.R627L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100943128; called by muse, mutect2, varscan2
- AHNAK2 | c.8560G>C p.G2854R | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as COSV100314886, COSV100319241, COSV60908726; called by muse, mutect2, varscan2
- ALG6 | c.229G>C p.A77P | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673585; called by muse, mutect2, varscan2
- ANKRD12 | c.4900G>C p.E1634Q | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.134); catalogued as COSV100042288, COSV104383076; called by muse, mutect2, varscan2
- ATAD5 | c.3061G>T p.E1021* | Nonsense Mutation (SNP) | VAF 229/583 reads (39%) | catalogued as COSV100430294; called by muse, mutect2, varscan2
- ATP6V1B1 | c.883A>C p.S295R | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99314601; called by muse, mutect2, varscan2
- AUTS2 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 98/155 reads (63%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.481); catalogued as rs749321104, COSV100719751; called by muse, mutect2, varscan2
- BOD1L1 | c.8332C>T p.L2778F | Missense Mutation (SNP) | VAF 96/348 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV99240600; called by muse, mutect2, varscan2
- C1orf116 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376328889; called by muse, mutect2, varscan2
- COIL | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1006291653, COSV99538453; called by muse, mutect2, varscan2
- COL19A1 | c.1779T>G p.D593E | Missense Mutation (SNP) | VAF 118/306 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.341); catalogued as COSV100507747; called by muse, mutect2
- CRP | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 42/142 reads (30%) | catalogued as COSV99660800; called by muse, mutect2, varscan2
- CTTNBP2 | c.1649C>A p.P550Q | Missense Mutation (SNP) | VAF 144/221 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50459489; called by muse, mutect2, varscan2
- CTTNBP2 | c.1648C>G p.P550A | Missense Mutation (SNP) | VAF 144/217 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50421077, COSV99355100; called by muse, mutect2, varscan2
- DDX50 | c.2149G>T p.G717C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV101007330; called by muse, mutect2, varscan2
- DNAH5 | c.13423G>A p.G4475S | Missense Mutation (SNP) | VAF 106/372 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV99455399; called by muse, mutect2, varscan2
- EPHA4 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV99917685; called by muse, mutect2, varscan2
- FHOD3 | c.3556G>T p.E1186* (on ENST00000359247 / NM_001281739.3; = p.E1203* on NM_025135.5) | Nonsense Mutation (SNP) | VAF 38/181 reads (21%) | catalogued as COSV57183608, COSV99943496; called by muse, mutect2, varscan2
- FLG2 | c.2460T>A p.F820L | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV101166305; called by muse, mutect2, varscan2
- FTMT | c.11G>A p.C4Y | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100360493; called by muse, mutect2, varscan2
- FUBP1 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 124/306 reads (41%) | catalogued as COSV99629771; called by muse, mutect2, varscan2
- GATAD2A | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV99390846; called by muse, mutect2, varscan2
- GDAP1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs1475695228, COSV99619933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GON4L | c.6608T>G p.L2203R | Missense Mutation (SNP) | VAF 56/326 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99676138; called by muse, mutect2, varscan2
- GPR160 | c.1004T>C p.I335T | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs1419635274, COSV100576198; called by muse, mutect2, varscan2
- HAS3 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99544861; called by muse, mutect2, varscan2
- HDX | c.1061T>C p.M354T | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV99948188; called by muse, mutect2
- HELZ | c.4777G>T p.E1593* | Nonsense Mutation (SNP) | VAF 79/174 reads (45%) | catalogued as COSV100699121; called by muse, mutect2, varscan2
- HERC1 | c.1227A>C p.E409D | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV101497071; called by muse, mutect2, varscan2
- HPS3 | c.2614G>C p.D872H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV56055885, COSV99937709; called by muse, mutect2, varscan2
- HRNR | c.1544C>A p.S515Y | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.907); catalogued as COSV100914044; called by muse, mutect2, varscan2
- IL12B | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as rs1395936414, COSV99180390; called by muse, mutect2, varscan2
- IL12B | c.195C>G p.S65R | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV99180391; called by muse, mutect2, varscan2
- IL13RA1 | c.815A>G p.H272R | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100861766; called by muse, mutect2, varscan2
- ITPR1 | c.4079G>A p.R1360Q (on ENST00000354582; = p.R1345Q on NM_002222.7) | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.997); catalogued as rs1461379244, COSV100233638; called by muse, mutect2, varscan2
- JPH1 | c.247del p.R83Gfs*72 | Frame Shift Del (DEL) | VAF 61/198 reads (31%) | catalogued as COSV100646749; called by mutect2, pindel, varscan2
- KCNAB1 | c.334T>C p.F112L (on ENST00000490337 / NM_172160.3; = p.F101L on NM_003471.3) | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.646); catalogued as COSV100205296; called by muse, mutect2, varscan2
- KIAA1549L | c.5260G>A p.A1754T (on ENST00000321505; = p.A2051T on NM_012194.3) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV100382603; called by muse, mutect2, varscan2
- KRT6A | c.548T>C p.F183S | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100417308; called by muse, mutect2, varscan2
- LARP4B | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV100295795; called by muse, mutect2, varscan2
- LILRA5 | c.635T>A p.L212H | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100007163; called by muse, mutect2, varscan2
- MAN2A2 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs750890155, COSV100848066; called by muse, mutect2, varscan2
- MECOM | c.143C>A p.S48Y | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV101527958; called by muse, mutect2, varscan2
- MELK | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 164/411 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs374744271, COSV53197392; ClinVar: likely benign; called by muse, mutect2, varscan2
- METAP2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as COSV99705024; called by muse, mutect2, varscan2
- MMP2 | c.876G>T p.K292N | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.981); catalogued as COSV99528379; called by muse, mutect2, varscan2
- MUC16 | c.14642A>C p.K4881T | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.181); catalogued as COSV101202145; called by muse, mutect2, varscan2
- MYBPH | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV99704202; called by muse, mutect2, varscan2
- MYH15 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as rs1456283634, COSV99843170, COSV99844538; called by muse, mutect2, varscan2
- NBAS | c.5081G>A p.S1694N | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs757665960, COSV55731526, COSV99872075; called by muse, mutect2, varscan2
- OR6C65 | c.305T>C p.L102S | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV101110221, COSV65568345; called by muse, mutect2, varscan2
- PAM | c.1574T>C p.L525P | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173974; called by muse, mutect2, varscan2
- PCDHB14 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as rs782732320, COSV53386946; called by muse, mutect2, varscan2
- PCDHB14 | c.1502C>A p.A501D | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.049); catalogued as COSV99506384; called by muse, mutect2, varscan2
- PCDHGB4 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99549088; called by muse, mutect2, varscan2
- PCSK4 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.142); catalogued as rs765591904, COSV99278916; called by muse, varscan2
- PDCD4 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99701258; called by muse, varscan2
- PDZK1 | c.169A>G p.R57G | Missense Mutation (SNP) | VAF 81/205 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100777393; called by muse, mutect2, varscan2
- PLB1 | c.558T>C p.N186= | Splice Region (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100580111; called by muse, mutect2, varscan2
- PRELID1 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100293831; called by muse, mutect2, varscan2
- PRR35 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758673124, COSV99552352; called by muse, mutect2, varscan2
- PRRX1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 83/514 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99510509; called by muse, mutect2, varscan2
- RBMXL1 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99557198; called by muse, mutect2, varscan2
- RGS7 | c.384T>A p.Y128* | Nonsense Mutation (SNP) | VAF 120/419 reads (29%) | catalogued as COSV100471758, COSV58556334; called by muse, mutect2, varscan2
- RNF20 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1250049994, COSV100874341; called by muse, mutect2, varscan2
- RNPEP | c.626C>A p.T209N | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99821936; called by muse, mutect2, varscan2
- RP1 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99609160; called by muse, mutect2, varscan2
- SCUBE3 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99235398; called by muse, mutect2, varscan2
- SERPINB4 | c.979A>T p.K327* | Nonsense Mutation (SNP) | VAF 54/104 reads (52%) | catalogued as COSV100346058; called by muse, mutect2, varscan2
- SLC12A4 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100312444, COSV57925250; called by muse, mutect2, varscan2
- SLC22A3 | c.442T>A p.C148S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51718005, COSV99279512; called by muse, mutect2, varscan2
- SLC2A6 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782317059, COSV100902808; called by muse, mutect2, varscan2
- SLC44A3 | c.1871G>A p.R624K (on ENST00000271227 / NM_001114106.3; = p.R576K on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/578 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99598744; called by muse, mutect2, varscan2
- SLC5A4 | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs763489323, COSV99832204; called by muse, mutect2, varscan2
- SNED1 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100123581; called by muse, mutect2, varscan2
- SSTR4 | c.1118C>A p.P373Q | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV54799156; called by muse, mutect2, varscan2
- SYNE1 | c.19983G>C p.Q6661H (on ENST00000367255 / NM_182961.4; = p.Q6590H on NM_033071.3) | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99583553; called by muse, mutect2, varscan2
- TBX6 | c.646T>G p.Y216D | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99661848; called by muse, mutect2, varscan2
- TCEA3 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV101508354; called by muse, mutect2, varscan2
- TEX2 | c.2743A>G p.T915A (on ENST00000583097 / NM_001288733.2; = p.T922A on NM_018469.5) | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV99367611; called by muse, mutect2, varscan2
- TLN2 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776986439, COSV60885254; called by muse, mutect2, varscan2
- TNRC6C | c.3961A>G p.S1321G | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100050873; called by muse, mutect2, varscan2
- TRO | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV99437499; called by muse, mutect2, varscan2
- USP9X | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 104/225 reads (46%) | catalogued as COSV100199459, COSV100200273; called by muse, mutect2, varscan2
- ZCCHC12 | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1274558588, COSV100038612; called by muse, mutect2, varscan2
- ZNF394 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100529997; called by muse, mutect2, varscan2
- ZNF99 | c.1326A>T p.K442N | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.47); PolyPhen benign (0.158); catalogued as COSV101234000; called by muse, mutect2, varscan2
- ZP4 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 42/290 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as COSV100850806; called by muse, mutect2, varscan2
- ZXDB | c.478G>T p.G160C | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs751291946, COSV100886087, COSV100886101; called by muse, mutect2, varscan2
- ZXDB | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100886102; called by muse, mutect2, varscan2
- ABRAXAS2 | c.1022_1033del p.N341_S344del | In Frame Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel, varscan2
- ACVR2A | c.1405_1410dup p.R469_L470dup | In Frame Ins (INS) | VAF 44/69 reads (64%) | called by mutect2, pindel, varscan2
- CFAP58 | c.1558_1564del p.K520* | Frame Shift Del (DEL) | VAF 33/171 reads (19%) | called by mutect2, pindel, varscan2
- FUBP1 | c.1667del p.P556Lfs*109 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | called by mutect2, pindel, varscan2
- IFITM3 | c.177del p.W60Gfs*9 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- KCNJ8 | c.1192_1209del p.I398_S403del | In Frame Del (DEL) | VAF 28/120 reads (23%) | called by mutect2, varscan2
- MMP12 | c.83dup p.N28Kfs*2 | Frame Shift Ins (INS) | VAF 22/92 reads (24%) | called by mutect2, varscan2
- PLEKHH3 | c.957dup p.G320Rfs*154 | Frame Shift Ins (INS) | VAF 27/76 reads (36%) | called by mutect2, pindel, varscan2
- RXFP3 | c.770del p.G257Afs*52 | Frame Shift Del (DEL) | VAF 44/120 reads (37%) | called by mutect2, pindel, varscan2
- SFMBT1 | c.641dup p.F215Ifs*14 | Frame Shift Ins (INS) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- ACTL6B | c.462C>G p.L154= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV99355807; called by muse, mutect2, varscan2
- ADGRV1 | c.12714G>A p.Q4238= | Silent (SNP) | VAF 83/160 reads (52%) | catalogued as COSV101316669; called by muse, mutect2, varscan2
- BBX | c.1461A>T p.I487= | Silent (SNP) | VAF 82/351 reads (23%) | catalogued as COSV100362381; called by muse, mutect2, varscan2
- CASK | c.2244T>C p.H748= (on ENST00000378163 / NM_001367721.1; = p.H743= on NM_003688.3) | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as COSV100587876; called by muse, mutect2, varscan2
- DCAF4 | c.276G>T p.T92= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as COSV100611198; called by muse, mutect2, varscan2
- EMILIN2 | c.1587G>A p.G529= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99599032; called by muse, mutect2, varscan2
- FBXW7 | c.1737G>A p.G579= (on ENST00000281708 / NM_001349798.2; = p.G499= on NM_018315.5) | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as COSV99661809; called by muse, mutect2, varscan2
- GRK1 | c.606G>A p.G202= | Silent (SNP) | VAF 59/215 reads (27%) | catalogued as COSV100175494; called by muse, mutect2, varscan2
- HRNR | c.1545C>A p.S515= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as COSV100914043; called by muse, mutect2, varscan2
- JAKMIP3 | c.1935C>T p.A645= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs199817578; called by muse, mutect2
- LUZP4 | c.9G>A p.S3= | Silent (SNP) | VAF 53/132 reads (40%) | catalogued as COSV64219163; called by muse, mutect2, varscan2
- MAGEA1 | c.357C>T p.A119= | Silent (SNP) | VAF 143/345 reads (41%) | catalogued as COSV100756696; called by muse, mutect2, varscan2
- MRPS16 | c.390A>G p.T130= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100161154; called by muse, mutect2, varscan2
- OR2L3 | c.84C>T p.I28= | Silent (SNP) | VAF 68/225 reads (30%) | catalogued as COSV100741985, COSV100742083; called by muse, mutect2, varscan2
- OR2T2 | c.231C>T p.I77= | Silent (SNP) | VAF 83/1178 reads (7%) | catalogued as rs762445074, COSV100737665, COSV61618655; called by muse, mutect2
- PKHD1L1 | c.1887A>G p.K629= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as COSV101007053; called by muse, mutect2, varscan2
- PLEK | c.948G>A p.E316= | Silent (SNP) | VAF 49/229 reads (21%) | catalogued as COSV99311310; called by muse, mutect2, varscan2
- PLEKHH2 | c.1170T>C p.F390= | Silent (SNP) | VAF 73/169 reads (43%) | catalogued as COSV56751068; called by muse, mutect2, varscan2
- PNMA1 | c.18G>A p.L6= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV99679322; called by muse, mutect2, varscan2
- RTL5 | c.318C>T p.N106= | Silent (SNP) | VAF 68/162 reads (42%) | catalogued as COSV101030075; called by muse, mutect2, varscan2
- SEC14L2 | c.354G>A p.Q118= | Silent (SNP) | VAF 31/86 reads (36%) | catalogued as rs754799440, COSV100464840; called by muse, mutect2, varscan2
- SKIV2L | c.180G>A p.Q60= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV100952891; called by muse, mutect2, varscan2
- SREBF2 | c.786C>T p.G262= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs1043490403, COSV100761594; called by muse, mutect2, varscan2
- THAP7 | c.114G>A p.L38= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- TSPYL2 | c.1515T>A p.T505= | Silent (SNP) | VAF 44/194 reads (23%) | catalogued as COSV100966389; called by muse, mutect2, varscan2
- VWF | c.213G>A p.S71= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs1353200453, COSV99780541; called by muse, mutect2, varscan2
- ACP4 | chr19:50798381 del G | 3'Flank (DEL) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- LTBP4 | c.451+1356C>G | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs1239013930; called by muse, mutect2
- PHKB | c.2427+981G>A | Intron (SNP) | VAF 12/97 reads (12%) | catalogued as rs527426323, COSV100068872; called by muse, mutect2, varscan2
- RUSC1 | c.-87+46C>A | Intron (SNP) | VAF 86/280 reads (31%) | catalogued as COSV99430402; called by muse, mutect2, varscan2
